Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5444, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5444-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Collected:

Received:

Accession:

Case type: Surgical Case

DIAGNOSIS

(A) LEVEL 2B, LEFT:

No tumor present in five lymph nodes (0/5)

(B) RIGHT PARATRACHEAL:

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE LYMPH NODE (1/1)

Extracapsular extension is not identified

(C) LEVEL 2, RIGHT:

No tumor present in eight lymph nodes (0/8)

(D) WIDE FIELD TOTAL LARYNGECTOMY AND SUBTOTAL THYROIDECTOMY:

INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (6.3 CM), PRESENT LESS THAN 0.1 CM FROM THE ANTERIOR SOFT TISSUE EDGE AND EXTENDING INTO THYROID GLAND

Perineural and lymphovascular invasion are not identified

METASTATIC SQUAMOUS CELL CARCINOMA IN THREE OF TWENTY-ONE LYMPH NODE (3/21) WITH EXTRACAPSULAR EXTENSION

Parathyroid gland with no diagnostic abnormality

GROSS DESCRIPTION

(A) LEVEL 2B, LEFT - Six possible lymph nodes all less than 0.5 cm in greatest dimension and grossly unremarkable.

SECTION CODE: A1, five lymph nodes; A2, one bisected lymph node.

(B) RIGHT PARATRACHEAL - A 1.2 x 1.0 x 0.5 cm pink-tan unremarkable lymph node bisected and entirely submitted in

(C) LEVEL 2, RIGHT - A possible lymph node embedded within unremarkable adipose tissue. The two larger lymph nodes, approximately 1.0 cm in greatest dimension, are infiltrated by adipose tissue. The smaller lymph nodes are unremarkable.

SECTION CODE: C1, one lymph node bisected; C2, one lymph node bisected; C3, two lymph nodes; C4, two lymph nodes; C5, one lymph node bisected; C6, one lymph node bisected.

(D) WIDE FIELD TOTAL LARYNGECTOMY AND SUBTOTAL THYROIDECTOMY - A total laryngectomy (9.0 x 6.2 x 5.1 cm) with anterior musculature, right thyroid lobe (5.5 x 3.0 x 1.2 cm), and partial left thyroid lobe (2.5 x 2.0 x 2.0 cm).

An exophytic, firm, light tan tumor (6.3 x 3.0 x 3.0 cm) extending from the right aryepiglottic fold superficially to involve the false and true vocal cords bilaterally and extending 2.5 cm into the subglottis. The tumor extends into the soft tissue superiorly anterior to the thyroid cartilage and extending behind the hyoid bone coming to within 0.1 cm of the superficial margin. The tumor extends bilaterally through the cricothyroid membrane to invade the thyroid bilaterally and muscle superficially. On the left, the tumor invades anterior to the left arytenoid and comes to within 0.1 cm of the soft tissue in the pyriform sinus. Inferiorly, the tumor invades between the cricoid cartilage and the first tracheal ring. Although tumor surrounds the cricothyroid and thyroid cartilage,

[page 2 of 2]
**Surgical Pathology
Report**

Collected
Received

Pathologist:
Case type: Surgical Case

direct tumor invasion is not grossly evident. The tumor comes to within 1.2 cm of the trachial margin. The anterior soft tissue contains multiple palpable lymph nodes. A portion of firm gray epithelium surrounds a previous stoma.

INK CODE: Black - superior soft tissue adjacent to tumor behind hyoid.

SECTION CODE: D1-D5, mucosal margins surrounding larynx (D1, right piriform sinus; D2, cricoid posteriorly; D3, left piriform sinus; D4, epiglottis; D5, right AE fold); D6, trachial margin; D7, right cricoid and subglottic tumor; D8, right aryepiglottic fold; D9, (more medial) subglottic extension; D10, subglottic tumor; D11, tumor through cricothyroid membrane into muscle; D12, pre-epiglottic tumor; D13, tumor invading right thyroid; D14, right true and false vocal cords; D15, pre-epiglottic tumor at superficial margin; D16-D17, sections just right of midline; D18, tumor left of midline involving thyroid; D19-D21, tumor (more lateral) subglottic to supraglottic; D22, tumor at left piriform sinus, abutting margin; D23, additional section of left piriform sinus anterior to arytenoid; D24, section through stoma; D25-D29, lymph nodes from right side (D25, one lymph node bisected; D26, one lymph node trisected; D27, five whole nodules; D28, one nodule bisected; D29, two whole nodules); D30, two whole nodules centrally located; D31, two whole nodules centrally located; D32-D37, lymph nodes on left side (D32, one nodule bisected; D33, one nodule trisected; D34-D37, two whole nodules in each cassette).

Source: NCI Genomic Data Commons file 42b52dbd-660c-4c72-ac35-e0dcee6ceb5a (TCGA-CV-5444.7D30150F-CADD-48CF-8146-387B40529C56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).